Somatic mutation profile of tumor specimen BA2995D (aliquot aq-BA2995D) from BEATAML1.0 case 2281, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,191 days).
Specimen BA2995D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b72a5e-580b-4347-94d0-767def90444a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2969D (Solid Tissue Normal), aliquot aq-BA2969D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/555d0af7-554a-4828-936c-2c96586d5fb4

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 3, Silent 2, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.403A>G p.R135G (on ENST00000344691 / NM_001001890.3; = p.R162G on NM_001754.5) | Missense Mutation (SNP) | VAF 147/309 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519751, COSV55867213; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- BCOR | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV60718396; called by muse, mutect2
- DIRAS3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63970685; called by muse, mutect2, varscan2
- SIRT2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1409624182, COSV50875570; called by muse, mutect2
- SLC4A2 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59658891; called by muse, mutect2
- BCOR | c.3171_3172insGTACGGGAAAA p.Q1058Vfs*59 | Frame Shift Ins (INS) | VAF 47/201 reads (23%) | called by mutect2, pindel, varscan2
- C2orf74 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- F5 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 46/358 reads (13%) | called by muse, mutect2, varscan2
- HEATR1 | c.4811T>A p.I1604N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- EPOR | c.324G>A p.S108= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs375735369; called by muse, mutect2, varscan2
- SCAF8 | c.1677A>G p.K559= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- FEZ1 | c.-275C>T | 5'UTR (SNP) | VAF 62/146 reads (42%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85655097 C>T | 3'Flank (SNP) | VAF 60/607 reads (10%) | catalogued as rs761519576; called by muse, mutect2, varscan2
